Somatic mutation profile of tumor specimen ALCH-B3BU-TTP1-B (aliquot ALCH-B3BU-TTP1-B-1-0-D-A78R-36) from ALCHEMIST case ALCH-B3BU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.1 years (24,859 days).
Specimen ALCH-B3BU-TTP1-B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef4e8306-5f05-4a3f-83e9-dd825c23b244.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3BU-NB1-A (Blood Derived Normal), aliquot ALCH-B3BU-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6eff049-4803-48d8-b841-c052b239ccb7

The open-access MAF lists 99 somatic variants for this specimen: 61 protein-altering or splice-affecting, 23 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 23, Intron 7, Nonsense Mutation 7, Splice Region 4, 5'UTR 3, 3'UTR 2, 5'Flank 2, 3'Flank 1, Splice Site 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2240T>C p.L747S | Missense Mutation (SNP) | VAF 126/767 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397517097, COSV51772009, COSV99285477; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- LOXHD1 | c.3169C>T p.R1057* | Nonsense Mutation (SNP) | VAF 42/564 reads (7%) | catalogued as rs727505104; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 56/375 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs397514495, CM056067, CM920671, CM942120, COSV52675795, COSV52676870, COSV52730435, COSV53567603; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTR8 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.971); catalogued as rs200175322; called by muse, mutect2
- ACTRT1 | c.609C>A p.F203L | Missense Mutation (SNP) | VAF 66/371 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.474); catalogued as COSV64419006; called by muse, mutect2, varscan2
- ATP11C | c.2873C>A p.P958H | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.775); catalogued as COSV59570151; called by muse, mutect2
- CDH2 | c.1537G>T p.G513C | Missense Mutation (SNP) | VAF 64/438 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV99295564; called by muse, mutect2, varscan2
- DST | c.3352C>T p.R1118* (on ENST00000361203 / NM_001374722.1; = p.R792* on NM_001723.6) | Nonsense Mutation (SNP) | VAF 16/248 reads (6%) | catalogued as rs774552617; called by muse, mutect2
- EBF3 | c.970G>A p.V324I (on ENST00000355311 / NM_001375392.1; = p.V315I on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV62473138; called by muse, mutect2
- ERICH3 | c.4357G>T p.E1453* | Nonsense Mutation (SNP) | VAF 48/279 reads (17%) | catalogued as rs1443716041; called by muse, mutect2, varscan2
- GUF1 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 58/484 reads (12%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs1298018362; called by muse, mutect2, varscan2
- H2BW2 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.202); catalogued as rs1331859904; called by muse, mutect2, varscan2
- KCNV1 | c.944G>T p.R315M | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV52089462; called by muse, mutect2
- LAMB4 | c.328+1G>A p.X110_splice | Splice Site (SNP) | VAF 48/430 reads (11%) | catalogued as rs764296606, COSV52721141, COSV52730957; called by muse, mutect2, varscan2
- OR4A47 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 84/547 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1389479993, COSV71444870, COSV71444939; called by muse, mutect2, varscan2
- OR9G4 | c.755A>G p.Y252C | Missense Mutation (SNP) | VAF 79/548 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1565064492; called by muse, mutect2, varscan2
- SEZ6 | c.1882G>A p.D628N | Missense Mutation (SNP) | VAF 53/489 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778243824; called by muse, mutect2, varscan2
- SPTA1 | c.4545G>T p.W1515C | Missense Mutation (SNP) | VAF 113/738 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1291965982; called by muse, mutect2, varscan2
- STPG4 | c.519C>T p.P173= | Splice Region (SNP) | VAF 43/294 reads (15%) | catalogued as rs1254542385; called by muse, mutect2, varscan2
- TMEM171 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs774216272, COSV55130343; called by muse, mutect2, varscan2
- TMX2 | c.719G>T p.R240L | Missense Mutation (SNP) | VAF 73/510 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.744); catalogued as COSV53553966, COSV99559863; called by muse, mutect2, varscan2
- VCAN | c.4376C>T p.T1459M | Missense Mutation (SNP) | VAF 144/1092 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs747981537; called by muse, mutect2, varscan2
- ZNF345 | c.224C>A p.S75* | Nonsense Mutation (SNP) | VAF 21/196 reads (11%) | catalogued as rs1327022338; called by muse, mutect2
- ADAM29 | c.2168G>T p.R723L | Missense Mutation (SNP) | VAF 38/580 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- ADAMTSL1 | c.3743A>G p.Y1248C | Missense Mutation (SNP) | VAF 85/430 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTSL3 | c.2735A>G p.K912R | Missense Mutation (SNP) | VAF 16/445 reads (4%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); called by muse, mutect2
- ANKRD30A | c.3315C>A p.C1105* (on ENST00000611781; = p.C1049* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 19/128 reads (15%) | called by muse, mutect2, varscan2
- ASTN1 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 44/558 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.043); called by muse, mutect2
- CD1D | c.751G>T p.G251W | Missense Mutation (SNP) | VAF 63/516 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD79B | c.67+6G>C | Splice Region (SNP) | VAF 118/1008 reads (12%) | called by muse, mutect2, varscan2
- CD9 | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 58/321 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- CDC73 | c.877T>A p.Y293N | Missense Mutation (SNP) | VAF 89/882 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CDH18 | c.1129G>T p.V377L | Missense Mutation (SNP) | VAF 95/753 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- CDKN2A | c.356_357dup p.E120Rfs*27 | Frame Shift Ins (INS) | VAF 100/705 reads (14%) | called by mutect2, pindel, varscan2
- CLCC1 | c.1118C>T p.A373V (on ENST00000356970 / NM_001377464.1; = p.A323V on NM_015127.5) | Missense Mutation (SNP) | VAF 44/361 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- DCAF11 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 18/117 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); called by muse, varscan2
- DNAH7 | c.6583C>G p.P2195A | Missense Mutation (SNP) | VAF 52/505 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EIF2B4 | c.852C>G p.I284M (on ENST00000347454 / NM_001034116.2; = p.I283M on NM_015636.3) | Missense Mutation (SNP) | VAF 43/1152 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.37); called by muse, mutect2
- ELL | c.785A>T p.Q262L | Missense Mutation (SNP) | VAF 44/375 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ENAM | c.3396C>G p.D1132E | Missense Mutation (SNP) | VAF 27/274 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.241); called by muse, mutect2
- FAM83F | c.655C>A p.R219= | Splice Region (SNP) | VAF 13/119 reads (11%) | called by muse, mutect2, varscan2
- HPS5 | c.1029G>T p.L343F (on ENST00000349215 / NM_181507.2; = p.L229F on NM_007216.4) | Missense Mutation (SNP) | VAF 71/581 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTT | c.4636G>T p.V1546F | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFI44L | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 40/618 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KLHL26 | c.23G>T p.S8I | Missense Mutation (SNP) | VAF 11/79 reads (14%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP2K3 | c.420G>A p.M140I (on ENST00000342679 / NM_145109.3; = p.M111I on NM_002756.4) | Missense Mutation (SNP) | VAF 34/434 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2
- MUC16 | c.37249G>T p.E12417* | Nonsense Mutation (SNP) | VAF 34/343 reads (10%) | called by muse, mutect2
- MUC16 | c.3710C>A p.P1237Q | Missense Mutation (SNP) | VAF 79/592 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- NLRP14 | c.1811A>T p.K604M | Missense Mutation (SNP) | VAF 20/566 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2
- OPHN1 | c.579G>T p.K193N | Missense Mutation (SNP) | VAF 54/432 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCDH19 | c.2483C>G p.S828C (on ENST00000373034 / NM_001184880.2; = p.S781C on NM_020766.3) | Missense Mutation (SNP) | VAF 94/1040 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PRB4 | c.685C>A p.P229T | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- PSD | c.1746G>A p.K582= | Splice Region (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- RNF213 | c.9420_9422del p.C3140_R3141delinsW | In Frame Del (DEL) | VAF 26/174 reads (15%) | called by mutect2, pindel, varscan2
- SCFD2 | c.1791G>T p.M597I | Missense Mutation (SNP) | VAF 35/367 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.023); called by muse, mutect2
- SIRPB1 | c.728C>A p.A243D | Missense Mutation (SNP) | VAF 77/662 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- SLC25A31 | c.41T>A p.L14Q | Missense Mutation (SNP) | VAF 38/378 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- SLC49A3 | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- SLC6A8 | c.673C>A p.L225M | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); called by muse, mutect2
- TMC5 | c.437A>T p.Y146F | Missense Mutation (SNP) | VAF 18/687 reads (3%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.272); called by muse, mutect2
- USH2A | c.8418C>A p.C2806* | Nonsense Mutation (SNP) | VAF 41/375 reads (11%) | called by muse, mutect2, varscan2
- C11orf53 | c.690C>T p.T230= | Silent (SNP) | VAF 12/133 reads (9%) | called by muse, mutect2
- CAMSAP1 | c.1992C>T p.P664= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100409816; called by muse, mutect2, varscan2
- CDH20 | c.1998C>T p.D666= | Silent (SNP) | VAF 41/380 reads (11%) | catalogued as rs768110003; called by muse, mutect2, varscan2
- EGFR | c.2239T>C p.L747= | Silent (SNP) | VAF 123/765 reads (16%) | catalogued as rs397517095; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ENC1 | c.474A>T p.A158= | Silent (SNP) | VAF 106/765 reads (14%) | catalogued as rs747647836; called by muse, mutect2, varscan2
- FBLN2 | c.2973C>G p.G991= | Silent (SNP) | VAF 56/441 reads (13%) | called by muse, mutect2, varscan2
- FLT1 | c.2277G>T p.L759= | Silent (SNP) | VAF 25/561 reads (4%) | called by muse, mutect2
- FOXL1 | c.303C>G p.L101= | Silent (SNP) | VAF 111/869 reads (13%) | catalogued as rs1489189669; called by muse, mutect2, varscan2
- FSIP2 | c.2745T>C p.Y915= | Silent (SNP) | VAF 7/180 reads (4%) | called by muse, mutect2
- HJV | c.234C>A p.G78= | Silent (SNP) | VAF 52/418 reads (12%) | called by muse, varscan2
- IRX2 | c.1293G>T p.A431= | Silent (SNP) | VAF 42/342 reads (12%) | catalogued as rs751267570; called by muse, mutect2, varscan2
- ITGAM | c.1389C>A p.S463= | Silent (SNP) | VAF 101/747 reads (14%) | called by muse, mutect2, varscan2
- KIAA2012 | c.2274C>G p.P758= | Silent (SNP) | VAF 33/397 reads (8%) | catalogued as rs949028732; called by muse, mutect2
- KRT76 | c.1758C>A p.G586= | Silent (SNP) | VAF 26/251 reads (10%) | called by muse, varscan2
- MYH4 | c.3954A>G p.E1318= | Silent (SNP) | VAF 75/454 reads (17%) | called by muse, mutect2, varscan2
- OR2L5 | c.399C>A p.I133= | Silent (SNP) | VAF 62/950 reads (7%) | catalogued as COSV62365342; called by muse, mutect2
- OR51Q1 | c.450C>T p.I150= | Silent (SNP) | VAF 80/617 reads (13%) | called by muse, mutect2, varscan2
- OR52B6 | c.408C>T p.A136= | Silent (SNP) | VAF 20/137 reads (15%) | called by muse, mutect2, varscan2
- OR5D18 | c.339C>A p.S113= | Silent (SNP) | VAF 34/520 reads (7%) | catalogued as rs533831141, COSV61737068, COSV61738738; called by muse, mutect2
- OXR1 | c.6G>A p.T2= | Silent (SNP) | VAF 84/614 reads (14%) | catalogued as rs1042823071; called by muse, mutect2, varscan2
- PARP3 | c.177G>T p.G59= | Silent (SNP) | VAF 38/526 reads (7%) | called by muse, mutect2
- RRAGC | c.138A>T p.A46= | Silent (SNP) | VAF 25/533 reads (5%) | called by muse, mutect2
- SRP68 | c.1560G>C p.V520= | Silent (SNP) | VAF 22/459 reads (5%) | called by muse, mutect2
- AL353804.4 | chrX:73822597 del T | 5'Flank (DEL) | VAF 18/112 reads (16%) | catalogued as rs749665925; called by mutect2, varscan2
- ANKFY1 | c.1372+44del | Intron (DEL) | VAF 27/226 reads (12%) | called by mutect2, pindel, varscan2
- ARG1 | c.-51G>A | 5'UTR (SNP) | VAF 76/527 reads (14%) | called by muse, mutect2, varscan2
- B3GAT1 | c.-22G>T | 5'UTR (SNP) | VAF 44/245 reads (18%) | called by muse, mutect2, varscan2
- CBFB | c.*31C>T | 3'UTR (SNP) | VAF 34/368 reads (9%) | called by muse, mutect2
- CICP28 | chr7:56812163 G>T | 3'Flank (SNP) | VAF 15/95 reads (16%) | catalogued as rs1193185939; called by muse, mutect2, varscan2
- EEF1G | c.-20C>G | 5'UTR (SNP) | VAF 64/506 reads (13%) | catalogued as rs3741241; called by muse, mutect2, varscan2
- KANSL2 | c.974-1970G>T | Intron (SNP) | VAF 32/306 reads (10%) | catalogued as rs1221167503; called by muse, mutect2, varscan2
- METTL2B | c.*634T>C | 3'UTR (SNP) | VAF 43/364 reads (12%) | called by muse, mutect2, varscan2
- MS4A6E | c.147+544T>A | Intron (SNP) | VAF 33/297 reads (11%) | called by muse, mutect2, varscan2
- OSBPL9 | c.543+2372A>T | Intron (SNP) | VAF 17/264 reads (6%) | called by muse, mutect2
- PHLDB1 | c.1828-1140A>T | Intron (SNP) | VAF 52/513 reads (10%) | called by muse, mutect2
- RASGRF2 | c.1390+270C>T | Intron (SNP) | VAF 60/409 reads (15%) | called by muse, mutect2, varscan2
- VAC14 | c.1160+3248G>A | Intron (SNP) | VAF 26/251 reads (10%) | catalogued as rs772441291; called by muse, mutect2, varscan2
- VPS16 | chr20:2840739 C>G | 5'Flank (SNP) | VAF 86/607 reads (14%) | catalogued as rs1317644871, COSV62313652; called by muse, mutect2, varscan2
